Somatic mutation profile of tumor specimen BA3142D (aliquot aq-BA3142D) from BEATAML1.0 case 2612, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.3 years (19,823 days).
Specimen BA3142D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8beb1e2-29ae-498f-af81-96dacfed400c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3307D (Solid Tissue Normal), aliquot aq-BA3307D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd8259de-60ae-46b5-953f-f6a36a592b8a

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IBTK | c.2135G>A p.R712K | Missense Mutation (SNP) | VAF 184/434 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs764634715; called by muse, mutect2, varscan2
- FREM3 | c.6113C>T p.T2038I | Missense Mutation (SNP) | VAF 120/277 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
